Somatic mutation profile of tumor specimen TCGA-G4-6304-01A (aliquot TCGA-G4-6304-01A-11D-1924-10) from TCGA case TCGA-G4-6304, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.2 years (24,172 days).
Specimen TCGA-G4-6304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ecd19ea-b03d-4681-a3f9-931a65c02cba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6304-10A (Blood Derived Normal), aliquot TCGA-G4-6304-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad8c9e13-ae45-4054-939c-e4ea3ab59980

The open-access MAF lists 1,040 somatic variants for this specimen: 799 protein-altering or splice-affecting, 226 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 597, Silent 226, Frame Shift Del 134, Frame Shift Ins 25, Nonsense Mutation 24, Splice Site 10, Intron 8, Splice Region 6, RNA 5, In Frame Del 3, 3'UTR 1, 3'Flank 1.

Variants (750 of 1,040; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- AR | c.2623C>T p.H875Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs137852581, COSV65952830; ClinVar: pathogenic; called by mutect2, varscan2
- CP | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750451693, CM066766, COSV52831994; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 23/196 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 54/348 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SOX9 | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1567910689, COSV99818669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM216 | c.218G>A p.R73H (on ENST00000515837 / NM_001173990.3; = p.R12H on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/887 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201108965, CM100170, CM121485, COSV58426431, COSV58426505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel
- TUBA1A | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1555162323, CM145636, COSV99853818; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100229293; called by muse, mutect2, varscan2
- ABCA2 | c.5806G>A p.V1936M (on ENST00000614293; = p.V1906M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1384603674, COSV55798034; called by muse, mutect2
- ABCA8 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV99286611; called by muse, varscan2
- ABCB7 | c.1876G>A p.D626N (on ENST00000373394 / NM_001271696.3; = p.D627N on NM_004299.6) | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1367225834, COSV99504698; called by muse, mutect2, varscan2
- ABCC10 | c.3847G>T p.G1283C (on ENST00000372530 / NM_001198934.2; = p.G1255C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99767788; called by muse, mutect2, varscan2
- ABCC10 | c.4390G>A p.A1464T (on ENST00000372530 / NM_001198934.2; = p.A1436T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1333366666, COSV99767789; called by muse, mutect2, varscan2
- ABCC3 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99559633; called by muse, mutect2
- ABO | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV101505996; called by muse, mutect2
- AC092143.1 | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs587784504, COSV59248275; ClinVar: likely benign; called by mutect2, varscan2
- AC098582.1 | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.349); catalogued as rs1208278048, COSV52022305, COSV99986200; called by muse, mutect2
- ACAA1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156702815, COSV57174985; called by muse, mutect2, varscan2
- ACACA | c.5144T>C p.I1715T | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs760603191; called by muse, mutect2
- ACADS | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99656800; called by muse, mutect2, varscan2
- ACTB | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV59319076; called by muse, mutect2, varscan2
- ACVR1B | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV99231825; called by muse, mutect2
- ADAMTSL4 | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55003176; called by muse, mutect2, varscan2
- ADCY9 | c.1988A>T p.K663M | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV99570642; called by muse, mutect2
- ADGRE1 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs768955899, COSV51672392; called by muse, mutect2, varscan2
- ADRB2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs1209605702, COSV60005301; called by muse, mutect2
- AHDC1 | c.2917G>T p.G973C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV55940486, COSV55941017; called by muse, mutect2, varscan2
- AHNAK2 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV60921654; called by muse, mutect2, varscan2
- AHR | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54124724; called by muse, mutect2
- AK5 | c.248-1G>A p.X83_splice (on ENST00000354567 / NM_174858.3; = p.X57_splice on NM_012093.4) | Splice Site (SNP) | VAF 20/220 reads (9%) | catalogued as COSV58356449; called by muse, mutect2
- AKAP12 | c.2789C>A p.A930E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV53575029, COSV99484145; called by muse, mutect2
- AKAP13 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100774334; called by muse, mutect2, varscan2
- ALDH1A2 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99991019; called by muse, mutect2, varscan2
- ALK | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as rs770006984, COSV66567814; ClinVar: uncertain significance; called by mutect2, varscan2
- ALOXE3 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs375389989; called by mutect2, varscan2
- AMBRA1 | c.3044G>A p.R1015H (on ENST00000458649 / NM_001367468.1; = p.R925H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs760302067, COSV100095062; called by muse, mutect2
- AMOTL1 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs912368715, COSV100504662; called by muse, mutect2, varscan2
- ANK3 | c.2744G>A p.R915H (on ENST00000280772 / NM_001320874.2; = p.R49H on NM_001149.3) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs750209484, COSV55049916, COSV55068340; called by mutect2, varscan2
- ANKRD11 | c.4970C>T p.S1657L | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749114664, COSV56362701; called by muse, mutect2
- ANKRD35 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62910962; called by muse, mutect2, varscan2
- ANO2 | c.2675C>T p.S892L (on ENST00000356134 / NM_001278597.3; = p.S896L on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767967144, COSV59020201, COSV59035280; called by mutect2, varscan2
- ANO4 | c.881C>T p.A294V (on ENST00000392977 / NM_001286615.2; = p.A259V on NM_178826.4) | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1258502826, COSV54590058; called by muse, mutect2
- ANPEP | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs148047449; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 24/197 reads (12%) | catalogued as rs759218332; called by mutect2, varscan2
- ANXA6 | c.1196A>G p.Q399R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62907465; called by muse, mutect2, varscan2
- AP1M2 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV99140976; called by muse, mutect2, varscan2
- AP5Z1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100804204; called by muse, mutect2, varscan2
- APBB1 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs770078300, COSV100192988; called by muse, mutect2, varscan2
- APBB3 | c.1284G>T p.Q428H (on ENST00000357560 / NM_133173.2; = p.Q435H on NM_006051.3) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60365831; called by muse, mutect2, varscan2
- APC | c.3814dup p.S1272Ffs*4 | Frame Shift Ins (INS) | VAF 23/169 reads (14%) | catalogued as CI058181; called by mutect2, pindel, varscan2
- AQP11 | c.332del p.G111Afs*9 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | catalogued as rs749836421; called by mutect2, pindel, varscan2
- ARAF | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV51693862; called by muse, mutect2
- ARHGAP33 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 18/202 reads (9%) | catalogued as COSV99139584; called by muse, mutect2
- ARL13A | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs766355429, COSV65880327; called by muse, mutect2, varscan2
- ARL16 | c.255del p.C86Afs*19 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | catalogued as rs752241785; called by mutect2, pindel, varscan2
- ARL6IP1 | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV58614635; called by muse, mutect2
- ARMS2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV101600751; called by muse, mutect2, varscan2
- ARSJ | c.1292del p.N431Mfs*86 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | catalogued as rs1562327720; called by mutect2, varscan2
- ASB12 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62857240; called by muse, varscan2
- ASB14 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.727); catalogued as rs772971599, COSV55702053; called by muse, mutect2, varscan2
- ASCC3 | c.4923+2T>C p.X1641_splice | Splice Site (SNP) | VAF 22/161 reads (14%) | catalogued as COSV64973100; called by muse, mutect2, varscan2
- ASIC2 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56767463, COSV99860863; called by muse, mutect2, varscan2
- ATAD2 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as rs575694809, COSV54883597; called by muse, mutect2, varscan2
- ATG4D | c.1027T>C p.Y343H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100470358; called by muse, mutect2
- ATM | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV53760935; called by muse, mutect2, varscan2
- ATP11B | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV60030643; called by muse, mutect2, varscan2
- ATP13A4 | c.808+1G>T p.X270_splice | Splice Site (SNP) | VAF 23/220 reads (10%) | catalogued as COSV55072047; called by muse, mutect2, varscan2
- AUH | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774105176, COSV57866965; called by mutect2, varscan2
- AUTS2 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs747879933, COSV61386016; called by muse, mutect2, varscan2
- AXIN2 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100196856; called by muse, mutect2, varscan2
- BBC3 | c.667del p.R223Efs*6 (on ENST00000449228 / NM_001127240.3; = p.E189Rfs*26 on NM_014417.5) | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as COSV56263193; called by mutect2, pindel, varscan2
- BCL11A | c.2117G>A p.R706H (on ENST00000335712 / NM_001365609.1; = p.R740H on NM_018014.4) | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59633508; called by muse, mutect2
- BCL2L14 | c.607+2T>C p.X203_splice | Splice Site (SNP) | VAF 12/168 reads (7%) | catalogued as COSV99845236; called by muse, mutect2
- BCL9L | c.4388del p.P1463Rfs*94 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs1555172524; called by mutect2, pindel, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | catalogued as rs751794665; called by mutect2, varscan2
- BCOR | c.3724C>T p.Q1242* (on ENST00000378444 / NM_001123385.2; = p.Q1208* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 17/173 reads (10%) | catalogued as COSV100653832, COSV60711125; called by muse, mutect2, varscan2
- BEX1 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV65580486; called by muse, mutect2
- BIRC6 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.389); catalogued as COSV70202594; called by muse, mutect2, varscan2
- BMP2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776834114, COSV66577307; called by muse, mutect2, varscan2
- BMP2 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.272); catalogued as COSV101122111; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 31/144 reads (22%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BZW1 | c.854dup p.N285Kfs*54 | Frame Shift Ins (INS) | VAF 64/480 reads (13%) | catalogued as rs774640795; called by mutect2, varscan2
- C1orf94 | c.596A>G p.D199G (on ENST00000488417 / NM_001134734.2; = p.D9G on NM_032884.5) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.633); catalogued as rs762142573, COSV100975167; called by mutect2, varscan2
- C22orf31 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as rs1385567215, COSV99326494; called by muse, mutect2, varscan2
- CA7 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 56/529 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); catalogued as COSV100623804, COSV58157149; called by muse, mutect2, varscan2
- CACNA1B | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV53144290; called by muse, mutect2, varscan2
- CACNA1F | c.5432A>G p.Q1811R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100545265; called by muse, mutect2, varscan2
- CACNA2D2 | c.2968A>G p.I990V (on ENST00000479441 / NM_001174051.3; = p.I983V on NM_006030.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56566025; called by muse, mutect2, varscan2
- CACNG2 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100268991; called by muse, mutect2
- CADPS | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200699296, COSV51871986; called by muse, varscan2
- CADPS2 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100465148; called by muse, mutect2
- CAMK1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369335655, COSV56538349; called by muse, mutect2
- CAMSAP2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs756562159, COSV52673736; called by muse, mutect2, varscan2
- CAPN10 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54377797, COSV54378652; called by muse, mutect2, varscan2
- CAPN10 | c.1542G>T p.W514C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54377843; called by muse, mutect2
- CAPZA3 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs1185224368, COSV99856766; called by muse, mutect2, varscan2
- CASR | c.2537C>T p.P846L (on ENST00000490131; = p.P923L on NM_000388.4) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56139215; called by muse, mutect2, varscan2
- CCDC130 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs942851688; called by muse, mutect2
- CCDC141 | c.2705T>A p.M902K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55377434; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC6 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs749668592, COSV99569762; called by muse, mutect2, varscan2
- CCN2 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV63466864; called by muse, mutect2, varscan2
- CCNA2 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV54666864; called by muse, mutect2, varscan2
- CCNL2 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV68766866; called by muse, mutect2
- CCT8L2 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV100743012, COSV63463805; called by muse, mutect2, varscan2
- CCT8L2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100743013; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 14/176 reads (8%) | catalogued as rs773911500; called by mutect2, pindel
- CDC42BPG | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs762926788, COSV100712137; called by mutect2, varscan2
- CDH8 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54869708; called by muse, mutect2, varscan2
- CDRT15 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.728); catalogued as COSV101415155; called by muse, mutect2, varscan2
- CEMIP2 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs151327312; called by muse, mutect2, varscan2
- CENPH | c.314G>T p.R105M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV51585259, COSV51585476; called by muse, mutect2, varscan2
- CEP120 | c.1907C>A p.P636H | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100070911; called by muse, mutect2
- CEP290 | c.6917_6920del p.R2306Nfs*40 | Frame Shift Del (DEL) | VAF 72/531 reads (14%) | catalogued as rs1177923180; called by mutect2, pindel, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP44 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55613499; called by muse, mutect2, varscan2
- CHCHD5 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1276029855, COSV61424231; called by muse, mutect2, varscan2
- CHD8 | c.2240A>G p.Y747C (on ENST00000646647 / NM_001170629.2; = p.Y468C on NM_020920.4) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101303195; called by muse, mutect2, varscan2
- CHN1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 51/455 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV69297293; called by muse, mutect2, varscan2
- CHRDL2 | c.1244T>C p.L415P (on ENST00000376332 / NM_001304415.1; = p.P433= on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99734034; called by muse, mutect2, varscan2
- CHSY1 | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV99574154; called by muse, mutect2, varscan2
- CIAPIN1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV101275913; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs752250702; called by mutect2, varscan2
- CLDN9 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100172312, COSV60911129; called by muse, mutect2
- CLIP1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958782845, COSV100211757; called by muse, mutect2
- CLU | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100324417; called by muse, mutect2
- CNOT1 | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV55314621; called by muse, mutect2
- CNOT11 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56821246; called by muse, mutect2, varscan2
- CNTN3 | c.2752A>G p.K918E | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV55177618; called by muse, mutect2, varscan2
- COL22A1 | c.4277G>A p.G1426D | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280087; called by muse, mutect2
- COL6A2 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs778932545, COSV100154082; called by muse, mutect2, varscan2
- COL6A2 | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs1382122104, COSV100154084; called by muse, mutect2
- COL7A1 | c.6877G>A p.G2293S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM124809, COSV60398321; called by muse, mutect2, varscan2
- COLGALT1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539028568, COSV53108736, COSV99395226; called by mutect2, varscan2
- COPS6 | c.905T>C p.M302T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs749647179, COSV57996655; called by muse, mutect2, varscan2
- COPS7A | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV57526498, COSV99976548; called by muse, mutect2, varscan2
- CR1L | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54328684; called by muse, mutect2, varscan2
- CRACD | c.501del p.K167Nfs*82 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs1180697484, COSV99950174; called by mutect2, pindel
- CREBBP | c.4282C>T p.R1428C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387351570, COSV52121437; called by muse, mutect2, varscan2
- CRKL | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV100574190, COSV100574227; called by muse, mutect2
- CROCC | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758565180, COSV65013462; called by muse, mutect2, varscan2
- CRYGB | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53680578; called by muse, mutect2, varscan2
- CRYGD | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs564197072, COSV100006116; ClinVar: benign; called by muse, mutect2, varscan2
- CSF2RA | c.290A>G p.H97R | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV62625528; called by muse, mutect2
- CSMD3 | c.4385C>T p.T1462M (on ENST00000297405 / NM_001363185.1; = p.T1358M on NM_052900.3) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200071288, COSV52353951; called by mutect2, varscan2
- CTDSP2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs745667327, COSV101222790; called by muse, mutect2, varscan2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 26/198 reads (13%) | catalogued as rs759618368; called by mutect2, varscan2
- CTSW | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV57171938; called by muse, mutect2
- CUL4B | c.2693A>G p.Y898C | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341048; called by muse, mutect2
- CUL9 | c.6031C>T p.R2011C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs747856369, COSV99335856; called by muse, mutect2, varscan2
- CX3CL1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99136461; called by muse, mutect2
- CXorf58 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191542694, COSV101003125, COSV64858528; called by muse, mutect2, varscan2
- CYP11B2 | c.1486del p.L496Sfs*178 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | catalogued as CD104299; called by mutect2, pindel, varscan2
- DAAM2 | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99226662; called by muse, mutect2
- DCC | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100502221; called by muse, mutect2, varscan2
- DCP1A | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868986097, COSV53689456; called by muse, mutect2, varscan2
- DDX24 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs759757010, COSV58213293; called by muse, mutect2, varscan2
- DDX47 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1478546957, COSV100774621; called by muse, mutect2, varscan2
- DDX58 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101153156; called by muse, mutect2
- DENND6A | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60767812; called by muse, mutect2, varscan2
- DEUP1 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV99977492; called by muse, mutect2, varscan2
- DGCR2 | c.1613del p.G538Vfs*111 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | catalogued as rs1278157389; called by mutect2, pindel, varscan2
- DHRS1 | c.664G>C p.A222P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99852446; called by muse, mutect2, varscan2
- DHX36 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 14/196 reads (7%) | catalogued as COSV100273851; called by muse, mutect2
- DIDO1 | c.3781C>T p.P1261S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99826752; called by muse, mutect2, varscan2
- DIP2A | c.903A>G p.E301= | Splice Region (SNP) | VAF 11/46 reads (24%) | catalogued as COSV59481886; called by muse, mutect2, varscan2
- DMD | c.3230C>T p.A1077V | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.729); catalogued as COSV63772675; called by muse, mutect2
- DMTF1 | c.1481T>A p.F494Y | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV100487350, COSV100487482; called by muse, mutect2, varscan2
- DNAH1 | c.8051C>A p.P2684H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV70232057; called by muse, mutect2, varscan2
- DNAH7 | c.9020C>T p.A3007V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs759580198, COSV56774137; called by mutect2, varscan2
- DNAH8 | c.4962G>A p.W1654* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100546751; called by muse, mutect2, varscan2
- DNAI4 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as rs1483091147, COSV64030279, COSV64031470; called by muse, mutect2, varscan2
- DNAI4 | c.1385A>T p.H462L | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs754533938, COSV64022628; called by muse, mutect2, varscan2
- DNAJB7 | c.884dup p.K296Efs*3 | Frame Shift Ins (INS) | VAF 52/450 reads (12%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC21 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs561936948, COSV57761468; called by muse, varscan2
- DNAJC6 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs762235583, COSV54778254; called by muse, mutect2
- DNAJC8 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1475082074, COSV55282247, COSV55282606; called by muse, mutect2
- DNASE1 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV99892637; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.4486C>T p.P1496S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99377547; called by muse, mutect2, varscan2
- DOCK7 | c.3118C>T p.R1040C (on ENST00000635253 / NM_001367561.1; = p.R1009C on NM_033407.3) | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99225594; called by muse, mutect2
- DPP8 | c.479G>A p.R160H (on ENST00000341861 / NM_001320875.2; = p.R144H on NM_017743.6) | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373358439, COSV55682381; called by muse, mutect2
- DROSHA | c.2798A>C p.H933P | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100757779; called by muse, mutect2
- DSEL | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as COSV100025977; called by muse, mutect2
- DST | c.1510C>T p.Q504* (on ENST00000361203 / NM_001374722.1; = p.Q178* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 49/400 reads (12%) | catalogued as COSV55026073; called by muse, mutect2, varscan2
- DTL | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV65342798; called by muse, mutect2
- DYM | c.1886A>G p.Y629C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53988367; called by muse, mutect2
- DYNC1H1 | c.8945G>A p.R2982H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64138096; called by muse, mutect2, varscan2
- DYNC2H1 | c.7607G>A p.R2536H | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs376790555; ClinVar: uncertain significance; called by muse, mutect2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- ECT2 | c.1097T>C p.V366A (on ENST00000392692 / NM_001349098.2; = p.V335A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1229462948, COSV99221729; called by muse, mutect2
- EEA1 | c.2431del p.I811Sfs*2 | Frame Shift Del (DEL) | VAF 18/157 reads (11%) | catalogued as rs776707160; called by mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1692C>A p.F564L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62568492, COSV62568976; called by muse, mutect2, varscan2
- EFCAB6 | c.3787A>G p.S1263G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV53067219; called by muse, mutect2, varscan2
- EHD2 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99622171; called by muse, mutect2
- EIF4B | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs779198667, COSV50405093; called by muse, mutect2, varscan2
- EIF4G1 | c.601C>T p.R201C (on ENST00000346169 / NM_198241.3; = p.R5C on NM_004953.5) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1246719099, COSV59992222; called by muse, mutect2, varscan2
- EIF4G2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101151071; called by muse, mutect2
- EPB41L3 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs769159490, COSV59461373; called by mutect2, varscan2
- ERC2 | c.1341G>C p.E447D | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV55640386; called by muse, mutect2, varscan2
- ERN2 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs752855204, COSV56837904, COSV99892161; called by muse, mutect2, varscan2
- ESM1 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV67318758, COSV67318919; called by muse, mutect2
- ESPL1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs375659071; called by muse, mutect2, varscan2
- ETV1 | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV99624310; called by muse, mutect2, varscan2
- EVI2A | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 57/501 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV55987340, COSV99907676; called by muse, mutect2, varscan2
- EXOSC5 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs377456809, COSV55371023; called by muse, mutect2, varscan2
- EYA2 | c.155G>T p.R52I | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV100427195; called by muse, mutect2
- FAM193A | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs372896676, COSV61196054; called by muse, mutect2, varscan2
- FARSB | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.16); catalogued as COSV56048422; called by muse, mutect2
- FASN | c.4125C>T p.D1375= | Splice Region (SNP) | VAF 7/43 reads (16%) | catalogued as rs17848940, COSV60757702; called by mutect2, varscan2
- FASTK | c.1428G>A p.R476= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99879918; called by muse, mutect2, varscan2
- FAT1 | c.6766G>A p.A2256T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752611276, COSV71675024; called by muse, mutect2, varscan2
- FAT1 | c.5630dup p.V1878Cfs*8 | Frame Shift Ins (INS) | VAF 19/101 reads (19%) | catalogued as rs1560943587; called by mutect2, pindel, varscan2
- FAT3 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.147); catalogued as COSV53140973; called by muse, mutect2
- FAT3 | c.11812G>A p.V3938M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1053068067, COSV53115727, COSV53140989; called by muse, varscan2
- FAT3 | c.13504G>A p.V4502M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs373934891; called by muse, mutect2, varscan2
- FAT4 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.99); catalogued as COSV67892869; called by muse, mutect2, varscan2
- FBN2 | c.6412del p.D2138Tfs*111 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | catalogued as COSV52520596; called by mutect2, pindel, varscan2
- FBXL20 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99234599; called by muse, mutect2, varscan2
- FBXL20 | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99234602; called by muse, mutect2
- FBXO11 | c.620C>T p.T207I (on ENST00000403359 / NM_001190274.2; = p.T123I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV57023054; called by muse, mutect2, varscan2
- FBXO30 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.387); catalogued as rs781145248, COSV99395363; called by muse, mutect2, varscan2
- FCHO2 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs1219677561, COSV59274971; called by muse, mutect2
- FGD2 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99236529; called by muse, varscan2
- FGF13 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV59548161; called by muse, mutect2, varscan2
- FKBP3 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as COSV99361113; called by muse, mutect2, varscan2
- FLAD1 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV99422893; called by muse, mutect2, varscan2
- FLNA | c.4196A>G p.K1399R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100775042; called by muse, mutect2, varscan2
- FLT4 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs757057248, COSV56098792; called by muse, mutect2, varscan2
- FLVCR2 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV99471497; called by muse, mutect2, varscan2
- FLYWCH1 | c.1240G>A p.A414T (on ENST00000253928 / NM_001308068.2; = p.A413T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs529892902, COSV54146544; called by muse, mutect2, varscan2
- FMR1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.595); catalogued as rs372019441, COSV54425115; called by muse, mutect2
- FNIP2 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs751093209, COSV52442459; called by muse, mutect2, varscan2
- FPR2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs750225501, COSV60674565; called by muse, mutect2, varscan2
- FREM2 | c.4537G>A p.D1513N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1486881602, COSV54835048; called by muse, mutect2, varscan2
- FRMD4B | c.779A>C p.Y260S | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV68331540; called by muse, mutect2
- FRMPD3 | c.4817G>A p.S1606N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as COSV52193875; called by muse, mutect2, varscan2
- FRMPD3 | c.5194A>G p.N1732D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV99346866; called by muse, mutect2, varscan2
- FTH1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV99861379; called by muse, mutect2, varscan2
- FYB2 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV58586886; called by muse, mutect2, varscan2
- G2E3 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs766510980, COSV99249842; called by muse, mutect2, varscan2
- GABRA6 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV50885490; called by muse, mutect2
- GALNT13 | c.285A>T p.R95S | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV67228906; called by muse, mutect2, varscan2
- GAPVD1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as rs374437143; called by mutect2, varscan2
- GART | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs372288271; called by muse, mutect2
- GATAD2A | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53072668; called by muse, mutect2, varscan2
- GDAP1 | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as COSV55186352; called by muse, mutect2, varscan2
- GDF6 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.41); catalogued as COSV54625250, COSV54626250; called by muse, mutect2
- GFRA4 | c.667G>A p.G223R (on ENST00000319242 / NM_145762.3; = p.G193R on NM_022139.4) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1453741035, COSV99293949; called by muse, mutect2, varscan2
- GGT5 | c.287T>G p.I96S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757553753, COSV99571793; called by mutect2, varscan2
- GLIS3 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1156755159, COSV100174595; called by muse, mutect2, varscan2
- GOT2 | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV99803498; called by muse, mutect2, varscan2
- GPRASP1 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV100851058; called by muse, mutect2, varscan2
- GRAP2 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100703112; called by muse, mutect2, varscan2
- GRHL2 | c.1394T>C p.I465T | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV99307634; called by muse, mutect2
- GRIA3 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.279); catalogued as COSV52060487; called by muse, mutect2, varscan2
- GRID1 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138984541, COSV60013597; called by muse, mutect2, varscan2
- GRM3 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV64467011; called by muse, mutect2, varscan2
- GUCY1A2 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV99976255; called by muse, mutect2, varscan2
- GULP1 | c.843+2T>C p.X281_splice | Splice Site (SNP) | VAF 29/291 reads (10%) | catalogued as COSV63070164; called by muse, mutect2, varscan2
- GYS1 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV99621089; called by muse, varscan2
- H4C7 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV55100518; called by muse, mutect2
- HAO2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58040898; called by muse, mutect2, varscan2
- HAS3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as rs985994450, COSV54706505; called by muse, mutect2, varscan2
- HAUS5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as rs1311633223, COSV52548741; called by muse, mutect2
- HBS1L | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV63201860; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | catalogued as rs746547303; called by mutect2, pindel
- HCFC2 | c.2348A>G p.Q783R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99983231; called by muse, mutect2, varscan2
- HEATR1 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV100857762; called by muse, mutect2
- HEATR4 | c.721T>C p.Y241H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100620567; called by muse, mutect2, varscan2
- HECTD1 | c.5288A>G p.D1763G | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101237470; called by muse, mutect2, varscan2
- HELZ | c.5627C>T p.A1876V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs758080750, COSV100698984; called by muse, mutect2, varscan2
- HHIP | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs754903217, COSV56840591, COSV56841602; called by muse, mutect2, varscan2
- HIBADH | c.852+2T>C p.X284_splice | Splice Site (SNP) | VAF 26/350 reads (7%) | catalogued as COSV99607408; called by muse, mutect2
- HINT3 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV99996223; called by muse, mutect2
- HIP1R | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs532716787, COSV99459167; called by muse, mutect2, varscan2
- HIPK2 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752518503, COSV61229001, COSV61229658; called by muse, mutect2, varscan2
- HIPK4 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.773); catalogued as COSV99396956; called by mutect2, varscan2
- HLA-A | c.893G>A p.W298* | Nonsense Mutation (SNP) | VAF 18/149 reads (12%) | catalogued as COSV65143767; called by muse, mutect2
- HLA-DPA1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV69822408; called by muse, mutect2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 42/215 reads (20%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXB3 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV61144363; called by muse, mutect2
- HRNR | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs551059466, COSV100912675; called by muse, mutect2, varscan2
- HSD17B4 | c.736C>A p.L246I (on ENST00000414835 / NM_001199291.3; = p.L221I on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV56338516, COSV99820079; called by muse, mutect2
- HSD17B4 | c.1816G>A p.G606R (on ENST00000414835 / NM_001199291.3; = p.G581R on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/526 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56337441; called by muse, varscan2
- HSF4 | c.757A>G p.S253G (on ENST00000521374 / NM_001040667.3; = p.L257= on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99263607; called by muse, mutect2, varscan2
- HSPA13 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53465757; called by muse, mutect2, varscan2
- HSPA13 | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.649); catalogued as rs763489416, COSV53465764; called by mutect2, varscan2
- HTATSF1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1340934996, COSV54478671; called by muse, varscan2
- HTRA3 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972404421, COSV56469353; called by muse, mutect2
- IDI1 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV101191266; called by muse, mutect2, varscan2
- IFI16 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV55536547, COSV55539683; called by muse, mutect2, varscan2
- IFNAR2 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV59749874; called by muse, mutect2, varscan2
- IGSF3 | c.1182C>A p.S394R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59594398; called by muse, mutect2, varscan2
- IL1RAPL1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1365228431, COSV100149498, COSV56245289; called by muse, mutect2
- IL27RA | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99652339; called by muse, mutect2, varscan2
- IL4R | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as rs753969425; called by muse, mutect2, varscan2
- IMPA2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs754589142, COSV52320717, COSV99302712; called by mutect2, varscan2
- INCENP | c.1780G>A p.E594K (on ENST00000394818 / NM_001040694.2; = p.E590K on NM_020238.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1363372627, COSV53914060; called by muse, mutect2, varscan2
- INKA2 | c.559del p.A187Hfs*20 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as rs751997684, COSV61878369; called by mutect2, pindel, varscan2
- INSR | c.2881C>T p.P961S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV57166984; called by muse, mutect2, varscan2
- INSRR | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs139920561; called by mutect2, varscan2
- INTS1 | c.6463G>A p.A2155T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs1185744208, COSV101248247; called by muse, mutect2
- INTS1 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as rs1370571557, COSV101248249; called by muse, mutect2, varscan2
- IQCA1 | c.1104dup p.Q369Tfs*10 | Frame Shift Ins (INS) | VAF 54/386 reads (14%) | catalogued as rs767039128; called by mutect2, pindel, varscan2
- IQSEC1 | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56225914; called by muse, mutect2, varscan2
- ISLR2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100679730; called by muse, mutect2
- ITM2C | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV58399807; called by muse, mutect2, varscan2
- JADE2 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50921731; called by muse, mutect2, varscan2
- JAKMIP2 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99509005; called by muse, mutect2
- KANK2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747769949, COSV100763330; called by muse, mutect2, varscan2
- KAT6A | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.176); catalogued as COSV55904531; called by muse, mutect2
- KCND3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56192249; called by muse, mutect2
- KCNH1 | c.2180C>T p.A727V (on ENST00000271751 / NM_172362.3; = p.A700V on NM_002238.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV55079668, COSV55090701; called by muse, mutect2, varscan2
- KCNH8 | c.2352del p.N785Tfs*10 | Frame Shift Del (DEL) | VAF 13/133 reads (10%) | catalogued as rs760381227; called by mutect2, pindel, varscan2
- KCNN4 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs201019335, COSV99487156; called by muse, mutect2, varscan2
- KCNT2 | c.3045G>A p.M1015I | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.146); catalogued as rs1358667695, COSV54092250, COSV99657417; called by muse, mutect2, varscan2
- KIAA0100 | c.4768G>T p.A1590S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV101197380; called by muse, mutect2
- KIAA0319 | c.2795G>A p.C932Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100985745; called by muse, mutect2, varscan2
- KIAA1109 | c.13420A>G p.N4474D | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99169855; called by muse, mutect2, varscan2
- KIAA2026 | c.2069del p.K690Rfs*3 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs1220524818; called by mutect2, varscan2
- KIF5C | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs768689068, COSV68480982; called by muse, mutect2
- KLHL5 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as COSV54676597; called by muse, mutect2
- KLK9 | c.93del p.N32Tfs*83 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as rs1218682589; called by mutect2, pindel
- KLRF1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as COSV99684516; called by muse, mutect2, varscan2
- KMT2B | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55859180; called by muse, mutect2
- KPNA1 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV60270128; called by muse, mutect2, varscan2
- KRT31 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs748743219, COSV52435034; called by muse, mutect2, varscan2
- KRT39 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs751328453, COSV62917911; called by muse, mutect2
- LAMA1 | c.3597del p.D1200Tfs*38 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | catalogued as COSV101057516, COSV67542370; called by mutect2, pindel, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 19/190 reads (10%) | catalogued as rs747409331; called by mutect2, pindel, varscan2
- LAMC3 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100735939; called by muse, mutect2
- LANCL2 | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54648343; called by muse, mutect2, varscan2
- LCT | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV99930208; called by muse, mutect2
- LDB2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.218); catalogued as COSV58761887, COSV58784552; called by muse, mutect2
- LHX5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV99922542; called by muse, mutect2, varscan2
- LILRA2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs775694135, COSV99253800; called by muse, mutect2, varscan2
- LIMK1 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs141412371; called by muse, mutect2, varscan2
- LIPE | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs757895823, COSV99734346; called by muse, mutect2
- LMOD3 | c.637del p.I213Yfs*4 | Frame Shift Del (DEL) | VAF 50/413 reads (12%) | catalogued as rs773282804; called by mutect2, varscan2
- LMTK3 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54310976; called by muse, mutect2, varscan2
- LONRF3 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100504591; called by muse, mutect2
- LPAR5 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61692485; called by muse, mutect2
- LRIG1 | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV56243977; called by muse, mutect2
- LRIT1 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs764126784, COSV100927970; called by muse, mutect2, varscan2
- LRP2 | c.469T>C p.C157R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55550458; called by mutect2, varscan2
- LRRC61 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs573247336, COSV56231687; called by mutect2, varscan2
- LRRTM1 | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV54440271, COSV54444061; called by muse, mutect2
- LRTOMT | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as rs748522399, COSV99194439; called by muse, mutect2, varscan2
- MAGEA6 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV100262948; called by muse, mutect2
- MAGEC1 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.168); catalogued as COSV53581346, COSV99596277; called by muse, mutect2
- MAP1B | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs778270951, COSV57094018; called by mutect2, varscan2
- MAP2K7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185925179, COSV67607748, COSV67607971; called by muse, varscan2
- MAP7D1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs887307554, COSV60217255; called by muse, mutect2
- MAPK6 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1383832953, COSV55929821; called by muse, mutect2
- MAPT | c.2123G>A p.S708N (on ENST00000262410 / NM_001377265.1; = p.S316N on NM_005910.5) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99290549, COSV99291150; called by muse, mutect2, varscan2
- MATN2 | c.2744A>G p.Q915R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as rs1298752786, COSV99646926; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MCAM | c.481T>C p.C161R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877923; called by muse, mutect2, varscan2
- MCCC1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs369093010, COSV55606205; called by mutect2, varscan2
- MCF2 | c.259T>G p.C87G | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV100645014; called by muse, mutect2
- MCM7 | c.2102A>G p.Y701C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100385111; called by muse, mutect2, varscan2
- MEAK7 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100640429; called by muse, mutect2, varscan2
- MED30 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99816115; called by muse, mutect2, varscan2
- MINDY4 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519129; called by muse, mutect2, varscan2
- MMP3 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as rs143174783; called by muse, mutect2
- MNAT1 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54192222; called by muse, mutect2
- MPDZ | c.2399A>C p.E800A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.227); catalogued as COSV100064146; called by muse, varscan2
- MREG | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54374836; called by muse, mutect2
- MRGPRF | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs1209793175, COSV100307908; called by muse, mutect2, varscan2
- MRNIP | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52974172; called by muse, mutect2
- MROH7 | c.3499del p.R1167Efs*23 | Frame Shift Del (DEL) | VAF 20/186 reads (11%) | catalogued as rs35459699, COSV59879142; called by mutect2, pindel, varscan2
- MTAP | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs200708704, COSV66477701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTOR | c.7016G>T p.R2339I | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63877764; called by muse, mutect2
- MUC16 | c.4727C>A p.S1576Y | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101200922, COSV67449444; called by muse, mutect2, varscan2
- MXRA8 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.921); catalogued as COSV58510376; called by muse, mutect2
- MYH6 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs139182991; called by muse, mutect2, varscan2
- MYH7 | c.2218A>G p.K740E | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100806469; called by muse, mutect2, varscan2
- N4BP1 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52211834; called by muse, mutect2
- N4BP1 | c.1829del p.N610Mfs*8 | Frame Shift Del (DEL) | VAF 28/261 reads (11%) | catalogued as rs1567431035; called by mutect2, pindel, varscan2
- NAA16 | c.1548dup p.E517* | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs749241638; called by mutect2, varscan2
- NAALAD2 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100428705; called by muse, mutect2, varscan2
- NARS2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99807454; called by muse, mutect2
- NCAPD2 | c.128-1G>T p.X43_splice | Splice Site (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100217376, COSV59698790; called by muse, mutect2
- NCR1 | c.37C>T p.L13= | Splice Region (SNP) | VAF 5/46 reads (11%) | catalogued as COSV52557502; called by muse, mutect2
- NDST1 | c.344T>A p.I115N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55788777; called by muse, mutect2, varscan2
- NEK10 | c.879A>G p.I293M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.336); catalogued as COSV58286237; called by muse, mutect2, varscan2
- NELFA | c.1265del p.P422Rfs*67 (on ENST00000542778; = p.P411Rfs*67 on NM_005663.5) | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as COSV100373062; called by mutect2, pindel, varscan2
- NELFA | c.1114G>A p.A372T (on ENST00000542778; = p.A361T on NM_005663.5) | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1476304618, COSV56389444; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NIPBL | c.1513del p.R505Efs*35 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs34314728; called by mutect2, pindel, varscan2
- NKX6-2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV100888351; called by muse, mutect2
- NLRP2 | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99672562; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL6 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99955073; called by muse, mutect2, varscan2
- NOS1 | c.3962C>A p.P1321Q | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100501206; called by muse, mutect2
- NPAP1 | c.3068G>A p.S1023N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1257357231, COSV100275930; called by muse, mutect2
- NPAT | c.3117dup p.S1040Ifs*18 | Frame Shift Ins (INS) | VAF 8/67 reads (12%) | catalogued as rs1565305809; called by mutect2, pindel, varscan2
- NPHS1 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV100800184; called by muse, mutect2
- NPY | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs961184030, COSV99635988; called by muse, varscan2
- NPY | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184116367, COSV54215599; called by muse, varscan2
- NR5A2 | c.1345G>A p.V449I (on ENST00000367362 / NM_205860.3; = p.V403I on NM_003822.5) | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs750928806, COSV52653592; called by muse, mutect2, varscan2
- NRP1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV55171603; called by muse, mutect2
- NTHL1 | c.272A>G p.D91G (on ENST00000219066; = p.D83G on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99526471; called by muse, mutect2, varscan2
- NUGGC | c.1163T>C p.M388T | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1447915989, COSV58436720; called by muse, mutect2, varscan2
- NUMA1 | c.5713G>A p.G1905S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.388); catalogued as rs760554948, COSV99474935; called by muse, mutect2, varscan2
- NUP155 | c.2423C>T p.A808V (on ENST00000231498 / NM_153485.3; = p.A749V on NM_004298.4) | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99194232; called by muse, varscan2
- NUP210 | c.1961T>C p.V654A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1244082631, COSV99596808; called by muse, varscan2
- NWD1 | c.3535C>A p.R1179S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60346278; called by mutect2, varscan2
- OBSCN | c.7480C>T p.P2494S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.557); catalogued as COSV52780321, COSV52797645; called by muse, mutect2, varscan2
- OGDH | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56049041; called by muse, mutect2
- OOEP | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV64859369; called by muse, mutect2, varscan2
- OPCML | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV59445552; called by muse, mutect2, varscan2
- OR10P1 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs752834026, COSV59007072; called by mutect2, varscan2
- OR13C4 | c.841T>G p.S281A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as COSV52927603; called by muse, mutect2
- OR2B6 | c.430T>G p.L144V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV99773827; called by muse, mutect2, varscan2
- OR2F1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV101231326; called by muse, mutect2
- OR2G6 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375684573, COSV58576068; called by mutect2, varscan2
- OR51G2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as rs771383654, COSV100432203; called by mutect2, varscan2
- OR5K3 | c.254T>G p.F85C | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67350364; called by muse, mutect2, varscan2
- OR5T1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs780788505, COSV57303760; called by muse, mutect2, varscan2
- OSBPL8 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1449157972, COSV99675426; called by muse, mutect2, varscan2
- OSR2 | c.899G>A p.R300Q (on ENST00000297565 / NM_001142462.3; = p.G273S on NM_053001.3) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as COSV99882756; called by muse, mutect2
- OTOGL | c.1978C>A p.P660T (on ENST00000547103; = p.P651T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV72006654, COSV72006688; called by muse, mutect2, varscan2
- OXSM | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55002107; called by muse, mutect2, varscan2
- PARP11 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); catalogued as COSV99959206; called by muse, mutect2
- PARP14 | c.1366A>T p.T456S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV71735119; called by mutect2, varscan2
- PCDH11X | c.3026C>T p.T1009I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100009978, COSV100014223; called by muse, mutect2, varscan2
- PCDH11X | c.3475G>T p.D1159Y | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs758235623, COSV100014228; called by muse, mutect2, varscan2
- PCDH8 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131967; called by muse, mutect2
- PCDHA1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100974626, COSV65375514; called by muse, mutect2, varscan2
- PCDHA7 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV65336739; called by muse, mutect2, varscan2
- PCDHB1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60631214; called by muse, mutect2, varscan2
- PCDHB12 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs532396499, COSV53398691, COSV99507128; called by muse, mutect2
- PCDHGA8 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as rs375160983, COSV53926197; called by muse, mutect2, varscan2
- PCDHGA8 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53984526; called by muse, mutect2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCLO | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 86/668 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV61648749; called by muse, mutect2, varscan2
- PCNT | c.8475G>T p.E2825D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV100855916; called by muse, mutect2
- PCYOX1L | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs752236282, COSV51003648; called by muse, mutect2, varscan2
- PDE6A | c.1862T>A p.L621H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54929284; called by muse, mutect2, varscan2
- PDIA2 | c.1148del p.P383Lfs*93 | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | catalogued as rs1472796664; called by mutect2, pindel, varscan2
- PDLIM2 | c.535C>T p.R179* (on ENST00000397760; = p.R429* on NM_021630.6) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs369238305; called by muse, mutect2, varscan2
- PDLIM4 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV99516988; called by muse, mutect2
- PELI3 | c.222C>A p.S74R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.637); catalogued as COSV100291880; called by muse, mutect2
- PFKFB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | PolyPhen probably damaging (0.988); catalogued as rs1335499341, COSV65548814; called by muse, mutect2, varscan2
- PGAP1 | c.291T>A p.S97R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61327694; called by muse, mutect2
- PGBD5 | c.734C>T p.A245V (on ENST00000525115; = p.A314V on NM_001258311.2) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1488372662, COSV58413566; called by muse, mutect2
- PHETA1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771936757, COSV100825396; called by muse, mutect2, varscan2
- PHLDB1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs191697288, COSV61876790; called by muse, mutect2, varscan2
- PHLDB2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | catalogued as rs201915760, COSV67312595; called by muse, mutect2, varscan2
- PIK3C2G | c.192dup p.V65Cfs*16 | Frame Shift Ins (INS) | VAF 18/142 reads (13%) | catalogued as rs1565550462; called by mutect2, pindel, varscan2
- PIK3CD | c.1260G>T p.W420C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63130199; called by muse, mutect2, varscan2
- PIM2 | c.39del p.T15Pfs*48 | Frame Shift Del (DEL) | VAF 22/199 reads (11%) | catalogued as rs782496935, COSV99332044; called by mutect2, pindel, varscan2
- PIP4K2A | c.1090_1092del p.Y364del | In Frame Del (DEL) | VAF 19/132 reads (14%) | catalogued as rs756401311; called by mutect2, pindel, varscan2
- PITPNM3 | c.1670A>G p.Y557C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99338878; called by muse, mutect2, varscan2
- PKIB | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV99236579; called by muse, mutect2, varscan2
- PKLR | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM981570; called by muse, mutect2
- PKNOX1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs960556215, COSV52337628; called by muse, mutect2, varscan2
- PLAG1 | c.242+1G>C p.X81_splice | Splice Site (SNP) | VAF 13/121 reads (11%) | catalogued as COSV57613211; called by muse, mutect2, varscan2
- PLEC | c.8722G>A p.E2908K (on ENST00000322810 / NM_201380.4; = p.E2798K on NM_000445.5) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1554686064, COSV100517679; called by muse, mutect2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 29/176 reads (16%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG2 | c.1485C>T p.N495= | Splice Region (SNP) | VAF 7/41 reads (17%) | catalogued as rs539936502, COSV99217950; called by mutect2, varscan2
- PLXNA2 | c.4127G>A p.R1376H | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895987183, COSV65442575; called by muse, varscan2
- PLXNB3 | c.2372G>A p.G791D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs782080603, COSV100737777; called by muse, mutect2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as rs761459630; called by pindel, varscan2
- POC1A | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs954789669, COSV56591681; called by muse, mutect2
- POLR2J | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 41/500 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs746099610, COSV99484573; called by muse, mutect2
- POLRMT | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV73933359; called by muse, mutect2
- POTEF | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 90/796 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100665225; called by muse, mutect2, varscan2
- PPP1R3A | c.1498T>C p.S500P | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99493842; called by muse, mutect2
- PPP3CB | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 35/366 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100646246; called by muse, mutect2
- PPP4R4 | c.2171T>C p.M724T | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs1218091098, COSV100428912; called by muse, mutect2
- PRDM2 | c.852T>A p.D284E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151133690, COSV52443960, COSV52449298; called by mutect2, varscan2
- PRKD3 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52215197; called by muse, mutect2, varscan2
- PRKDC | c.1683T>A p.N561K | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV58057761; called by muse, mutect2
- PRPF6 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889828866, COSV99412592; called by muse, mutect2, varscan2
- PRRT3 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs772462161, COSV55977910; called by muse, mutect2, varscan2
- PRUNE2 | c.3437C>T p.A1146V | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.388); catalogued as COSV100945000; called by muse, mutect2
- PSKH2 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763331082, COSV52612653; called by muse, mutect2, varscan2
- PSMD7 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99542795; called by mutect2, varscan2
- PTCH1 | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.938); catalogued as rs372219420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTP4A2 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59774546; called by muse, mutect2, varscan2
- PTPRD | c.5455G>A p.G1819R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61962240; called by muse, mutect2, varscan2
- PTPRD | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61962248; called by muse, mutect2
- PTPRK | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs759799993, COSV63898058; called by muse, mutect2
- PTTG1IP | c.151T>C p.C51R | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs758698293, COSV100445950; called by muse, mutect2, varscan2
- PUS3 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917062; called by muse, mutect2, varscan2
- PXDN | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs1299920416, COSV53235688; called by muse, mutect2, varscan2
- PYM1 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1333952969, COSV100212690; called by muse, mutect2, varscan2
- RAB5A | c.339T>A p.N113K | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as COSV56084685; called by muse, mutect2
- RABGEF1 | c.1150G>A p.A384T (on ENST00000439720 / NM_001287061.2; = p.A371T on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs757460921, COSV53163751; called by muse, mutect2, varscan2
- RALGAPA1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 51/396 reads (13%) | catalogued as COSV51889117; called by muse, varscan2
- RALGAPA2 | c.5560G>A p.E1854K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs986717961, COSV52503578; called by muse, mutect2, varscan2
- RALGDS | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs1013125630, COSV100924535; called by muse, mutect2, varscan2
- RBAK | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.992); catalogued as rs1026909212, COSV62331951; called by muse, mutect2, varscan2
- RBP2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV51674286; called by muse, mutect2
- RBPJL | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373490352; called by muse, mutect2, varscan2
- RCOR2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs760637710, COSV100036331, COSV100036335; called by mutect2, varscan2
- RCVRN | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV99874320; called by muse, mutect2, varscan2
- RECK | c.1326del p.K442Nfs*27 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as rs71508012; called by mutect2, pindel
- RGS12 | c.3526A>G p.K1176E | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs760916479, COSV58750063; called by mutect2, varscan2
- RGS17 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99243299; called by muse, mutect2, varscan2
- RLIM | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60329809; called by muse, mutect2, varscan2
- RNF167 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs760638375, COSV99337215; called by muse, mutect2, varscan2
- RNF216 | c.1156A>G p.S386G (on ENST00000425013 / NM_207116.3; = p.S443G on NM_207111.4) | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66291588; called by muse, mutect2
- RNF40 | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100222280; called by muse, mutect2
- ROBO2 | c.2799G>T p.L933F | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV59923477; called by muse, mutect2, varscan2
- ROCK2 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55081454; called by muse, mutect2
- RPL10A | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV57690447; called by muse, mutect2, varscan2
- RPL14 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59083432; called by muse, mutect2, varscan2
- RPL24 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.61); catalogued as COSV67530070; called by muse, mutect2
- RRNAD1 | c.815_817del p.S272del | In Frame Del (DEL) | VAF 13/87 reads (15%) | catalogued as rs1379348872; called by mutect2, pindel, varscan2
- RSU1 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100590688; called by muse, mutect2
- RTN3 | c.3089dup p.A1031Gfs*28 (on ENST00000377819 / NM_001265589.2; = p.A235Gfs*28 on NM_006054.4) | Frame Shift Ins (INS) | VAF 51/254 reads (20%) | catalogued as rs747510098; called by mutect2, varscan2
- RUFY2 | c.1175T>A p.V392D | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99769423; called by muse, mutect2, varscan2
- RYR3 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.123); catalogued as COSV101212246, COSV101213818; called by muse, mutect2, varscan2
- SAGE1 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100187726; called by muse, mutect2
- SALL3 | c.2260C>A p.L754M | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101610038; called by muse, mutect2
- SCAF11 | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV101014574; called by muse, mutect2, varscan2
- SCUBE3 | c.2752+2T>C p.X918_splice | Splice Site (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99235051; called by muse, mutect2, varscan2
- SEC22C | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759546532, COSV52566072; called by muse, mutect2, varscan2
- SEL1L3 | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1240594228, COSV53545005; called by muse, mutect2
- SEMA4D | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358680; called by muse, mutect2
- SEMG2 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as rs904238348, COSV65647696; called by muse, mutect2
- SENP7 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100053728; called by muse, mutect2
- SF3B1 | c.922A>C p.S308R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV59220087; called by muse, mutect2, varscan2
- SFSWAP | c.2438C>T p.A813V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.978); catalogued as COSV99906316; called by muse, mutect2, varscan2
- SGO2 | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV63416205; called by muse, mutect2, varscan2
- SH3D21 | c.1985C>T p.P662L (on ENST00000453908 / NM_001162530.2; = p.P551L on NM_024676.5) | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs371850468; called by muse, mutect2, varscan2
- SH3RF2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs140312306; called by mutect2, varscan2
- SHMT2 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100197323; called by muse, mutect2, varscan2
- SHOC1 | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV59504081; called by muse, mutect2
- SHROOM3 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56034110; called by muse, mutect2
- SLA | c.49C>T p.P17S (on ENST00000338087 / NM_001045556.3; = p.P57S on NM_006748.4) | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55081082, COSV55088904; called by muse, mutect2
- SLC12A5 | c.2364del p.L789Cfs*38 (on ENST00000454036 / NM_001134771.2; = p.L766Cfs*38 on NM_020708.5) | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs1568866957; called by mutect2, pindel, varscan2
- SLC16A14 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54618869; called by muse, mutect2, varscan2
- SLC1A3 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54318245; called by muse, varscan2
- SLC22A7 | c.271A>G p.N91D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV101000858; called by mutect2, varscan2
- SLC23A1 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs1474852192, COSV54526084; called by muse, mutect2, varscan2
- SLC24A3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs761018781, COSV100039406; called by muse, mutect2, varscan2
- SLC2A9 | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as COSV53325120, COSV99305316; called by muse, mutect2
- SLC38A10 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV55846992; called by muse, mutect2, varscan2
- SLC46A2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100953497; called by muse, mutect2, varscan2
- SLC4A3 | c.2652del p.S885Afs*22 | Frame Shift Del (DEL) | VAF 27/219 reads (12%) | catalogued as rs760972612; called by mutect2, varscan2
- SLC4A5 | c.2329C>A p.L777M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as COSV61030163; called by muse, mutect2, varscan2
- SLC6A11 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as rs774891377, COSV54393953; called by mutect2, varscan2
- SLC6A14 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64148756; called by muse, mutect2
- SLC6A7 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57939324; called by muse, mutect2, varscan2
- SLC8A2 | c.2625C>A p.Y875* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99370249; called by muse, mutect2
- SLC9C2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV62947123; called by muse, mutect2
- SLFN5 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV100249773; called by muse, mutect2
- SLMAP | c.1366C>T p.R456* (on ENST00000428312 / NM_001377924.1; = p.R518* on NM_007159.5) | Nonsense Mutation (SNP) | VAF 16/272 reads (6%) | catalogued as COSV55851283; called by muse, mutect2
- SMAD4 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV61697343; called by muse, mutect2, varscan2
- SMC1A | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.053); catalogued as COSV100447635; called by muse, mutect2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SNRNP200 | c.5896T>G p.F1966V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as COSV55531178; called by muse, mutect2
- SNTG2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs185149623; called by muse, mutect2
- SOCS5 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV60605624; called by muse, mutect2, varscan2
- SOWAHD | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.566); catalogued as rs1369719389, COSV100673158; called by muse, mutect2
- SOX13 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65827085; called by muse, mutect2
- SPEF2 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200848371, COSV61545540, COSV61549421; called by muse, mutect2, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | catalogued as rs752907815; called by mutect2, varscan2
- SPPL2B | c.1565A>G p.Q522R | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.342); catalogued as COSV101476114; called by muse, mutect2, varscan2
- SPRY3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs775484840, COSV57143637; called by muse, mutect2, varscan2
- SPTA1 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV63756462; called by muse, varscan2
- SPTBN1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV61690646; called by muse, mutect2, varscan2
- SRPK3 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as CM1515151; called by muse, mutect2
- SRPX2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs374870686, COSV100884053; called by muse, mutect2, varscan2
- SRSF5 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as rs564129276; called by muse, mutect2, varscan2
- SSRP1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53480392; called by mutect2, varscan2
- ST3GAL1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | PolyPhen possibly damaging (0.65); catalogued as rs771438014, COSV60614664; called by muse, mutect2
- STEAP3 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748187004, COSV61529010; called by muse, mutect2, varscan2
- STK24 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925002; called by muse, mutect2
- STK33 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV100174380; called by muse, mutect2, varscan2
- STRIP2 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221943301, COSV50804158, COSV99974241; called by muse, varscan2
- STX4 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100572972; called by muse, mutect2, varscan2
- SULT2B1 | c.362T>C p.L121P (on ENST00000201586 / NM_177973.2; = p.L106P on NM_004605.2) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99572379; called by muse, mutect2, varscan2
- SUPT5H | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100782134; called by muse, mutect2
- SYNE1 | c.16804dup p.M5602Nfs*13 (on ENST00000367255 / NM_182961.4; = p.M5531Nfs*13 on NM_033071.3) | Frame Shift Ins (INS) | VAF 22/183 reads (12%) | catalogued as rs1368275632; called by mutect2, pindel, varscan2
- SYNE1 | c.8266del p.I2756* (on ENST00000367255 / NM_182961.4; = p.I2763* on NM_033071.3) | Frame Shift Del (DEL) | VAF 19/180 reads (11%) | catalogued as COSV54961656; called by mutect2, pindel, varscan2
- SYNE2 | c.10487C>T p.S3496F | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV100648317; called by muse, mutect2, varscan2
- TADA2B | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1410574674, COSV53827602; called by muse, mutect2, varscan2
- TAS1R1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as rs371838719, COSV60229201; called by muse, mutect2, varscan2
- TBK1 | c.824T>A p.V275D | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.125); catalogued as COSV100538337; called by muse, mutect2, varscan2
- TBK1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs199905735, CM1513131; ClinVar: uncertain significance; called by mutect2, varscan2
- TBL1X | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1035620161, COSV54280305; called by muse, mutect2, varscan2
- TBXT | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV99752803; called by muse, mutect2, varscan2
- TCOF1 | c.4415C>T p.P1472L (on ENST00000377797 / NM_001135243.1; = p.P1395L on NM_000356.4) | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs148367422; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TENM1 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 42/320 reads (13%) | catalogued as COSV100950587; called by muse, mutect2, varscan2
- TENM4 | c.7961C>T p.T2654I | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV53646440; called by muse, mutect2, varscan2
- TG | c.4862C>T p.T1621M | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs112003182, COSV99602578; called by muse, mutect2
- TGM5 | c.532C>A p.P178T (on ENST00000220420 / NM_201631.4; = p.P96T on NM_004245.4) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV99589242; called by muse, mutect2, varscan2
- THAP10 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99537986; called by muse, mutect2
- THOP1 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); catalogued as rs182189341, COSV100310727; called by muse, mutect2, varscan2
- THUMPD3 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV61506353; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TLE2 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53581439; called by muse, mutect2, varscan2
- TMEM132E | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV58695687; called by muse, mutect2
- TMEM267 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV67993254; called by muse, mutect2
- TNNT2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730881123, COSV52663840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC6A | c.2656G>A p.G886S | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs767104641, COSV59361122; called by muse, mutect2, varscan2
- TNRC6B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs765835653, COSV57287804; called by muse, mutect2, varscan2
- TOGARAM2 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs774586680, COSV65420684; called by muse, mutect2, varscan2
- TOMM70 | c.927C>G p.N309K | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV52524166; called by muse, mutect2, varscan2
- TP63 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.534); catalogued as rs375508394; called by muse, mutect2, varscan2
- TPI1 | c.143G>A p.G48E (on ENST00000229270; = p.G11E on NM_000365.6) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57535592, COSV57538775; called by muse, mutect2
- TRA2B | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs1300746356, COSV52026125; called by muse, mutect2
- TRERF1 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as rs527323317, COSV100551373; called by mutect2, varscan2
- TRIM41 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs532938397, COSV59320489; called by muse, mutect2, varscan2
- TRIM49 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61671318; called by muse, mutect2, varscan2
- TRMT6 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177607; called by muse, mutect2
- TRPA1 | c.2017del p.T673Hfs*23 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | catalogued as rs748693374; called by mutect2, pindel
- TRPC4 | c.2239C>T p.R747C (on ENST00000379705 / NM_016179.4; = p.R752C on NM_003306.3) | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765838206, COSV59000659; called by muse, mutect2, varscan2
- TRPC4AP | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99328776; called by muse, mutect2
- TSC22D1 | c.3146del p.P1049Lfs*38 (on ENST00000458659 / NM_183422.4; = p.P120Lfs*38 on NM_006022.4) | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs762485832; called by mutect2, pindel, varscan2
- TSGA10 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs201271167, COSV61822661; called by muse, mutect2, varscan2
- TSPAN18 | c.419C>A p.S140* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as COSV100418873; called by muse, mutect2, varscan2
- TSPOAP1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765140985, COSV52109382; called by muse, mutect2, varscan2
- TTC3 | c.5113A>G p.K1705E | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100695912; called by muse, mutect2
- TTLL12 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV99333704; called by muse, mutect2, varscan2
- TTN | c.98714G>A p.R32905H (on ENST00000591111; = p.R25481H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/258 reads (7%) | PolyPhen probably damaging (0.953); catalogued as rs973169397, COSV60033883; called by muse, mutect2
- TTN | c.93322G>A p.A31108T (on ENST00000591111; = p.A23684T on NM_003319.4) | Missense Mutation (SNP) | VAF 18/218 reads (8%) | PolyPhen probably damaging (0.998); catalogued as COSV60183861; called by muse, mutect2
- TTN | c.26891del p.N8964Tfs*27 (on ENST00000591111; = p.N8037Tfs*27 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/359 reads (9%) | catalogued as COSV60002819; called by mutect2, pindel, varscan2
- TTN | c.17518A>G p.I5840V (on ENST00000591111; = p.I4913V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/155 reads (13%) | PolyPhen benign (0); catalogued as COSV60183897; called by muse, mutect2, varscan2
- TUBGCP2 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as rs146854474; called by muse, mutect2, varscan2
- TUBGCP5 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs1172191445; called by muse, mutect2
- UBR4 | c.6986C>T p.A2329V | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); catalogued as rs1214713307, COSV64393951; called by muse, mutect2, varscan2
- UNC79 | c.3274G>T p.A1092S (on ENST00000393151 / NM_001346218.2; = p.A915S on NM_020818.5) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV56397700; called by muse, mutect2, varscan2
- UNKL | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258214532, COSV100061723; called by muse, mutect2, varscan2
- UPB1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs367569283; called by muse, mutect2, varscan2
- USP20 | c.2513-1G>T p.X838_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | catalogued as COSV59616191; called by mutect2, varscan2
- USP6NL | c.1247del p.P416Rfs*119 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | catalogued as COSV53213385; called by mutect2, varscan2
- UTP25 | c.2111T>C p.L704P | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1318974656, COSV101530972; called by muse, mutect2
- UXS1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1327555218, COSV51680035; called by muse, mutect2
- VAV2 | c.1412A>G p.H471R | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.321); catalogued as COSV100896083; called by muse, mutect2, varscan2
- VAV3 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58386812; called by muse, mutect2, varscan2
- VPS18 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55030585, COSV99592649; called by muse, mutect2, varscan2
- VSIR | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs149997496; called by muse, mutect2
- WDFY1 | c.1186A>C p.T396P | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV51791041; called by muse, mutect2, varscan2
- WDHD1 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100864442; called by muse, mutect2, varscan2
- WDR36 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.409); catalogued as rs756283539, COSV72411318; called by muse, mutect2, varscan2
- XPO4 | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs373913195; called by muse, varscan2
- ZBTB12 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64994330; called by muse, mutect2, varscan2
- ZBTB44 | c.393T>A p.N131K | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV63537810; called by muse, mutect2
- ZC3H13 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | catalogued as COSV99668719; called by muse, mutect2, varscan2
- ZC3H3 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226132852, COSV52789269; called by muse, mutect2, varscan2
- ZDHHC7 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766777560, COSV58211750; called by muse, mutect2, varscan2
- ZFHX4 | c.7811G>A p.R2604Q | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs985622422, COSV50642204; called by muse, mutect2
- ZFP57 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs552912198, COSV65306518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFYVE28 | c.2177T>A p.L726H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52114201; called by muse, mutect2, varscan2
- ZHX3 | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV100476558; called by muse, mutect2, varscan2
- ZMYM3 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1203855215, COSV100078265; called by muse, mutect2
- ZNF133 | c.452C>T p.A151V (on ENST00000316358 / NM_001352454.2; = p.A150V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1376636433, COSV104412923; called by muse, mutect2
- ZNF224 | c.231T>A p.N77K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.585); catalogued as COSV100425498; called by muse, mutect2, varscan2
- ZNF275 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs782671461, COSV100936261; called by muse, mutect2
- ZNF282 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs137930836; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF383 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100776786; called by muse, mutect2
- ZNF431 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100218972, COSV100219098; called by muse, mutect2
- ZNF479 | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100482970, COSV58644728; called by muse, mutect2, varscan2
- ZNF516 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs373968169; called by muse, mutect2, varscan2
- ZNF557 | c.503C>T p.T168I (on ENST00000414706 / NM_001044388.2; = p.T175I on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as COSV99422692; called by muse, mutect2, varscan2
- ZNF567 | c.1615G>A p.G539R (on ENST00000536254 / NM_001322913.1; = p.G508R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV62445970; called by muse, mutect2, varscan2
- ZNF587 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100299626; called by muse, mutect2, varscan2
- ZNF616 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1045852; called by muse, mutect2, varscan2
- ZNF628 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1455007058, COSV99220220; called by muse, mutect2, varscan2
- ZNF639 | c.1246C>A p.L416I | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.952); catalogued as COSV58383714; called by muse, mutect2, varscan2
- ZNF668 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56216496; called by muse, varscan2
- ZNF668 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56216508; called by muse, varscan2
- ZNF813 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375586651, COSV101124972; called by mutect2, varscan2
- ZNF831 | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1397413367, COSV64038382; called by muse, mutect2
- ZSCAN1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as rs1409636598, COSV56606935; called by muse, mutect2, varscan2
- ZXDB | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100885994; called by muse, mutect2
- ABCA12 | c.6327del p.F2109Lfs*25 (on ENST00000272895 / NM_173076.3; = p.F1791Lfs*25 on NM_015657.3) | Frame Shift Del (DEL) | VAF 29/255 reads (11%) | called by mutect2, pindel, varscan2
- ABCA2 | c.3812del p.P1271Qfs*6 (on ENST00000614293; = p.P1241Qfs*6 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- ACACA | c.1960A>T p.I654L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAM7 | c.1781del p.L594Yfs*29 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.1035del p.F346Sfs*42 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- ALMS1 | c.9920C>T p.A3307V | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- APC | c.4459_4465del p.T1487Yfs*18 | Frame Shift Del (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- APOBR | c.3248del p.G1083Afs*8 (on ENST00000431282; = p.G1092Afs*8 on NM_018690.4) | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, varscan2
- ATAD5 | c.611del p.K204Sfs*2 | Frame Shift Del (DEL) | VAF 23/241 reads (10%) | called by mutect2, pindel, varscan2
- ATG4D | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- ATRX | c.3145dup p.I1049Nfs*4 | Frame Shift Ins (INS) | VAF 44/327 reads (13%) | called by mutect2, varscan2
- ATXN2L | c.1509dup p.T504Hfs*33 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- AUTS2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.19); called by muse, mutect2
- BCAN | c.2516_2517del p.V839Afs*170 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by pindel, varscan2
- BCL3 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.178); called by muse, mutect2
- BPTF | c.8154del p.K2718Nfs*36 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by mutect2, varscan2
- BTNL8 | c.747del p.F249Lfs*6 | Frame Shift Del (DEL) | VAF 33/235 reads (14%) | called by mutect2, pindel, varscan2
- CACTIN | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CAT | c.203_204del p.R68Nfs*3 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by pindel, varscan2
- CCDC186 | c.2600del p.N867Ifs*4 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | called by mutect2, pindel, varscan2
- CCR5 | c.236dup p.L80Pfs*47 | Frame Shift Ins (INS) | VAF 26/210 reads (12%) | called by mutect2, pindel, varscan2
- CCT3 | c.591del p.K197Nfs*23 | Frame Shift Del (DEL) | VAF 37/229 reads (16%) | called by mutect2, varscan2
- CD248 | c.2229del p.R744Gfs*61 | Frame Shift Del (DEL) | VAF 16/147 reads (11%) | called by mutect2, pindel, varscan2
- CEMIP2 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- CPLX2 | c.98del p.K33Rfs*40 | Frame Shift Del (DEL) | VAF 19/181 reads (10%) | called by mutect2, pindel, varscan2
- CSN1S1 | c.536del p.N179Ifs*16 | Frame Shift Del (DEL) | VAF 16/141 reads (11%) | called by mutect2, pindel, varscan2
- CTCFL | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTPS1 | c.1727dup p.D577* | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel
- DMBT1 | c.7604del p.P2535Hfs*24 (on ENST00000338354 / NM_001377530.1; = p.P1778Hfs*24 on NM_004406.3) | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel, varscan2
- DMXL1 | c.1229del p.L410Yfs*17 | Frame Shift Del (DEL) | VAF 22/191 reads (12%) | called by mutect2, pindel, varscan2
- DNMT1 | c.1972-3del | Splice Region (DEL) | VAF 6/82 reads (7%) | called by mutect2, pindel
- DPYSL2 | c.23del p.N8Ifs*11 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- DRC1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- DSG2 | c.2981C>A p.P994H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- DYNC1I1 | c.615dup p.Q206Tfs*30 | Frame Shift Ins (INS) | VAF 31/307 reads (10%) | called by mutect2, pindel
- EEF1D | c.688del p.A230Lfs*55 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- ELOVL1 | c.596del p.K199Sfs*3 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- ERCC6L | c.3237A>G p.I1079M | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ERCC6L2 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ERCC6L2 | c.3991del p.T1331Hfs*50 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- EVC2 | c.1813T>C p.S605P | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.284); called by muse, mutect2
- FANCA | c.2730_2731dup p.W911Sfs*11 | Frame Shift Ins (INS) | VAF 14/113 reads (12%) | called by mutect2, varscan2
- FBXL5 | c.402del p.Q135Sfs*4 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel, varscan2
- FBXW10 | c.2737A>G p.I913V | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- FGD4 | c.644dup p.L215Ffs*4 | Frame Shift Ins (INS) | VAF 22/170 reads (13%) | called by mutect2, pindel, varscan2
- FHDC1 | c.304del p.W102Gfs*55 | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- FPGT-TNNI3K | c.264del p.F88Lfs*37 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel, varscan2
- FUT11 | c.103dup p.E35Gfs*241 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | called by mutect2, pindel
- GABRG1 | c.175del p.I59Ffs*10 | Frame Shift Del (DEL) | VAF 29/205 reads (14%) | called by mutect2, pindel, varscan2
- GCNT2 | c.159dup p.E54* | Frame Shift Ins (INS) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- GDF5 | c.205del p.A69Pfs*18 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1035del p.V346Yfs*20 | Frame Shift Del (DEL) | VAF 20/148 reads (14%) | called by mutect2, varscan2
- GLE1 | c.1365del p.K455Nfs*31 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- GLI3 | c.45dup p.V16Sfs*2 | Frame Shift Ins (INS) | VAF 11/106 reads (10%) | called by mutect2, pindel, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 16/157 reads (10%) | called by mutect2, pindel, varscan2
- KDM5B | c.906del p.A303Pfs*37 | Frame Shift Del (DEL) | VAF 52/320 reads (16%) | called by mutect2, varscan2
- KDM6A | c.3241del p.T1081Pfs*2 | Frame Shift Del (DEL) | VAF 32/240 reads (13%) | called by mutect2, pindel, varscan2
- KHNYN | c.238del p.D80Mfs*40 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- KIF18A | c.1996dup p.R666Kfs*29 | Frame Shift Ins (INS) | VAF 22/213 reads (10%) | called by mutect2, pindel, varscan2
- KRTAP10-7 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.094); called by muse, mutect2
- LIMA1 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- LONRF1 | c.1657dup p.I553Nfs*3 | Frame Shift Ins (INS) | VAF 36/313 reads (12%) | called by mutect2, varscan2
- LRP2 | c.1001del p.P334Qfs*72 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- LRR1 | c.860del p.L287Cfs*28 | Frame Shift Del (DEL) | VAF 21/213 reads (10%) | called by mutect2, pindel, varscan2
- LRRTM2 | c.1308del p.F436Lfs*5 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- LZTS3 | c.1459_1461del p.K487del (on ENST00000329152; = p.K441del on NM_001282533.2) | In Frame Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- MAP7D1 | c.245del p.P82Rfs*51 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- MDN1 | c.8032_8033del p.T2678Sfs*4 | Frame Shift Del (DEL) | VAF 26/210 reads (12%) | called by pindel, varscan2
- MMP9 | c.1547G>A p.C516Y | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPL32 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- MTSS1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); called by muse, mutect2
290 further variants in this file (49 protein-altering or splice-affecting, 226 silent, 15 other) are not listed here.
